CCDI case PBCFYG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/f0534c17-0599-4099-a42d-3579d0257ba6

Demographics
Sex at birth: female; Race: black or african american; Vital status: Dead.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 0.1 years (20 days).

Biospecimens (3 samples)
- Sample 0DRE0H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRE0P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRE0W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
